Somatic mutation profile of tumor specimen TCGA-DU-8165-01A (aliquot TCGA-DU-8165-01A-11D-2253-08) from TCGA case TCGA-DU-8165, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 60.1 years (21,964 days).
Specimen TCGA-DU-8165-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f376ba1-ed38-4e01-986c-40efa844d8ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-8165-10A (Blood Derived Normal), aliquot TCGA-DU-8165-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c64d8a83-ff88-42b1-91f8-6e31e58ee1ed

The open-access MAF lists 73 somatic variants for this specimen: 58 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 13, Frame Shift Del 3, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF26B | c.6070C>T p.R2024C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs367632094, COSV63636986; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.472C>A p.R158S | Missense Mutation (SNP) | VAF 39/125 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by muse, mutect2, varscan2
- ADAMTS20 | c.3827A>T p.Q1276L | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV67128014; called by muse, mutect2
- ANO1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV60281892; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746697998, CM1211288, COSV57747927; called by muse, mutect2, varscan2
- ATP9A | c.2778A>G p.I926M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.175); catalogued as COSV58763953; called by muse, mutect2, varscan2
- B3GNT3 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57952856; called by muse, mutect2
- BCLAF3 | c.1749T>G p.D583E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61413300; called by muse, mutect2, varscan2
- CALCR | c.1154G>A p.G385E (on ENST00000649521 / NM_001164737.2; = p.G369E on NM_001742.4) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.155); catalogued as rs781150787, COSV64006245; called by muse, mutect2, varscan2
- CCDC110 | c.1152C>G p.F384L | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV56869696; called by muse, mutect2, varscan2
- CFAP52 | c.1721A>G p.Y574C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53300284; called by muse, mutect2, varscan2
- COL3A1 | c.338C>G p.P113R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.617); catalogued as COSV58583054, COSV58588385, COSV58589906; called by muse, mutect2
- DCLK3 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV69362462; called by muse, mutect2, varscan2
- DGAT2L6 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778176074, COSV60717131; called by muse, mutect2, varscan2
- DMXL2 | c.5624A>G p.D1875G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV51841755; called by muse, mutect2, varscan2
- DSG1 | c.2953G>T p.G985C | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs1158803454, COSV57133735; called by muse, mutect2, varscan2
- EPHA10 | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.306); catalogued as COSV60402317; called by muse, mutect2, varscan2
- ERO1A | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs1160599462, COSV67470764; called by muse, mutect2, varscan2
- FAM83B | c.2494C>A p.H832N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV60919893; called by muse, mutect2, varscan2
- FLNC | c.6568C>T p.R2190C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs1474675847, COSV57951707; called by muse, mutect2, varscan2
- GAB4 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs745520066, COSV68753142; called by muse, mutect2, varscan2
- GNL3 | c.1044G>A p.Q348= | Splice Region (SNP) | VAF 4/44 reads (9%) | catalogued as COSV56476769; called by muse, mutect2
- GRIN3A | c.2827G>C p.G943R | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV62451493; called by muse, mutect2
- HS6ST2 | c.1211A>T p.N404I | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100897317, COSV63711110; called by muse, mutect2, varscan2
- ITGA2 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56857026; called by muse, mutect2, varscan2
- LILRA4 | c.218A>T p.K73I | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV52490658; called by muse, mutect2, varscan2
- LRP2 | c.7850G>A p.R2617Q | Missense Mutation (SNP) | VAF 114/315 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs534858438, COSV55543674, COSV55566491; called by muse, mutect2, varscan2
- LRP2 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749942746, COSV55543681; called by muse, mutect2, varscan2
- LRRIQ1 | c.4155A>T p.R1385S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV67826841; called by muse, mutect2, varscan2
- MARS2 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV56570805; called by muse, mutect2, varscan2
- MATN2 | c.1524T>G p.C508W | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54707583; called by muse, mutect2, varscan2
- MMP8 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV52631298; called by muse, mutect2, varscan2
- NR3C1 | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV51540458; called by muse, mutect2
- OR11L1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63313810, COSV63315822; called by muse, mutect2, varscan2
- OR2G6 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs370636108, COSV58575739; called by muse, mutect2, varscan2
- OR51A2 | c.470T>A p.L157Q | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66748180; called by muse, mutect2, varscan2
- OR52E8 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV66205164; called by muse, mutect2, varscan2
- OR52I2 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 84/299 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV57044444; called by muse, mutect2, varscan2
- OR9K2 | c.823G>A p.V275M (on ENST00000305377; = p.V253M on NM_001005243.1) | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.213); catalogued as COSV59531506; called by muse, mutect2, varscan2
- PLCB1 | c.2578G>T p.A860S | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV62040941; called by muse, mutect2, varscan2
- POM121L12 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV68692387; called by muse, mutect2, varscan2
- PTPRM | c.2009T>A p.L670H | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV59846901; called by muse, mutect2, varscan2
- SCN7A | c.2432G>A p.S811N | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.908); catalogued as COSV69269345; called by muse, mutect2, varscan2
- SHANK2 | c.5209C>G p.L1737V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs1555149145, COSV53588179; called by muse, mutect2, varscan2
- SLC7A14 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51578691; called by muse, mutect2, varscan2
- SOGA3 | c.1815C>G p.I605M | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs968882023, COSV64105386, COSV64106050; called by muse, mutect2
- SRSF11 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63936718; called by muse, mutect2
- SSTR4 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV54797250; called by muse, mutect2
- SYTL4 | c.1993G>T p.A665S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV52165804; called by muse, mutect2, varscan2
- USP31 | c.2179T>C p.Y727H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV54849903; called by muse, mutect2, varscan2
- ZFHX4 | c.1576T>G p.S526A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV50554391; called by muse, mutect2, varscan2
- ZNF536 | c.3760G>T p.G1254W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as COSV62819864, COSV62820758, COSV62834133; called by muse, mutect2, varscan2
- ADGRL2 | c.1791del p.K597Nfs*21 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- HNF1B | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- SLC39A1 | c.188_198del p.A63Efs*25 | Frame Shift Del (DEL) | VAF 21/116 reads (18%) | called by mutect2, pindel, varscan2
- SPATA31E1 | c.691del p.L231* | Frame Shift Del (DEL) | VAF 46/311 reads (15%) | called by pindel, varscan2*
- COL22A1 | c.1632C>T p.D544= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs373172764; called by muse, mutect2, varscan2
- COLGALT2 | c.732G>A p.R244= | Silent (SNP) | VAF 50/198 reads (25%) | catalogued as rs372560078; called by muse, mutect2, varscan2
- ECRG4 | c.234C>G p.P78= | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as rs767847581, COSV53000004, COSV99430300; called by muse, mutect2, varscan2
- FAM47C | c.618G>A p.P206= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as rs200547398, COSV63724314; called by muse, mutect2, varscan2
- FAT2 | c.3450T>C p.A1150= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as rs1428814861, COSV55814734; called by muse, mutect2
- PCDHA7 | c.330G>T p.V110= | Silent (SNP) | VAF 195/579 reads (34%) | catalogued as COSV65342383; called by muse, mutect2, varscan2
- PSG11 | c.888T>C p.N296= | Silent (SNP) | VAF 42/157 reads (27%) | catalogued as COSV60453914; called by muse, mutect2, varscan2
- RPTN | c.561A>G p.R187= | Silent (SNP) | VAF 19/611 reads (3%) | catalogued as COSV60166556; called by muse, mutect2
- SCN1A | c.1638A>G p.E546= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV57662734; called by muse, mutect2, varscan2
- SH3RF2 | c.879G>A p.R293= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs1296961286, COSV63037580; called by muse, mutect2, varscan2
- SLIT2 | c.3234C>T p.D1078= | Silent (SNP) | VAF 85/185 reads (46%) | catalogued as rs573018203, COSV56560099; called by muse, mutect2, varscan2
- TIGD6 | c.267C>A p.I89= | Silent (SNP) | VAF 114/256 reads (45%) | catalogued as COSV57060586; called by muse, mutect2, varscan2
- TLR8 | c.1485C>T p.F495= (on ENST00000218032 / NM_138636.5; = p.F513= on NM_016610.4) | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV54316314; called by muse, mutect2
- DCHS2 | n.1546G>T | RNA (SNP) | VAF 13/49 reads (27%) | catalogued as COSV59719677; called by muse, mutect2, varscan2
- HUWE1 | c.8206+141G>T | Intron (SNP) | VAF 19/125 reads (15%) | catalogued as COSV99470995; called by muse, mutect2, varscan2
